Somatic mutation profile of tumor specimen C3N-02789-01 (aliquot CPT0186010007) from CPTAC case C3N-02789, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage II; FIGO stage: Stage II; Tumor grade: G2; Age at diagnosis: 61.9 years (22,610 days).
Specimen C3N-02789-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a47351e6-d4e7-4170-af25-5aa29f730b12.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02789-31 (Blood Derived Normal), aliquot CPT0187210002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67c05788-480c-4594-a9d3-3d5224fcf847

The open-access MAF lists 575 somatic variants for this specimen: 366 protein-altering or splice-affecting, 121 silent, 88 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 258, Silent 121, Frame Shift Del 61, Intron 53, 3'UTR 15, Frame Shift Ins 14, Nonsense Mutation 11, Splice Region 8, Splice Site 8, 3'Flank 6, 5'UTR 5, In Frame Del 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVR1 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 36/444 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121912678, CM061633, COSV55115924; ClinVar: pathogenic; called by muse, mutect2
- ARID1A | c.6472C>T p.R2158* | Nonsense Mutation (SNP) | VAF 118/296 reads (40%) | hotspot (GDC flag); catalogued as COSV61370611, COSV61381711; called by muse, mutect2, varscan2
- CCND1 | c.857C>T p.T286I | Missense Mutation (SNP) | VAF 33/103 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57119829, COSV99919330; called by muse, mutect2, varscan2
- CORO1A | c.400G>A p.V134M | Missense Mutation (SNP) | VAF 117/466 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs397514755, CM132738; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 88/576 reads (15%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- HPS1 | c.972del p.M325Wfs*6 | Frame Shift Del (DEL) | VAF 57/166 reads (34%) | catalogued as rs281865082, CD982691; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- IQSEC2 | c.804del p.Y269Tfs*3 (on ENST00000642864 / NM_001111125.3; = p.Y64Tfs*3 on NM_015075.2) | Frame Shift Del (DEL) | VAF 32/127 reads (25%) | catalogued as rs886041481, CD162113; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- PIK3R1 | c.1397_1399del p.L466del (on ENST00000521381 / NM_181523.3; = p.L196del on NM_181504.4) | In Frame Del (DEL) | VAF 85/131 reads (65%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- TGM1 | c.790C>T p.R264W | Missense Mutation (SNP) | VAF 40/775 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs201868387, CM065484; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- WRN | c.3382del p.S1128Vfs*34 | Frame Shift Del (DEL) | VAF 48/188 reads (26%) | catalogued as rs778872619; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- A3GALT2 | c.980G>A p.R327Q | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.46); catalogued as rs1048664670; called by muse, mutect2, varscan2
- ABCA1 | c.6152G>A p.R2051H | Missense Mutation (SNP) | VAF 87/659 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778400988, COSV66072762; called by muse, mutect2, varscan2
- ACTA2 | c.1102G>A p.G368R | Missense Mutation (SNP) | VAF 57/351 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as CM142267; called by muse, mutect2, varscan2
- ACTN2 | c.2645C>T p.A882V | Missense Mutation (SNP) | VAF 149/729 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as COSV63973157; called by muse, mutect2, varscan2
- ADGRA1 | c.1067C>T p.A356V | Missense Mutation (SNP) | VAF 11/318 reads (3%) | SIFT tolerated (0.28); PolyPhen benign (0.048); catalogued as rs1414583313, COSV66927890; called by muse, mutect2
- ADGRA2 | c.1562G>A p.R521H | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.197); catalogued as rs376864601; called by muse, mutect2
- AJAP1 | c.862G>A p.V288I | Missense Mutation (SNP) | VAF 105/317 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs750590324; called by muse, mutect2, varscan2
- ALPK3 | c.4399G>A p.V1467I | Missense Mutation (SNP) | VAF 65/155 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0.3); catalogued as rs538711539; called by muse, mutect2, varscan2
- ALPL | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 223/572 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as CM980081, COSV66376464, COSV66376627; called by muse, mutect2, varscan2
- ANKMY1 | c.1307C>T p.P436L | Missense Mutation (SNP) | VAF 18/420 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1288808246; called by muse, mutect2
- AOC2 | c.952A>G p.S318G | Missense Mutation (SNP) | VAF 34/487 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.418); catalogued as rs1454687636; called by muse, mutect2
- ARAP2 | c.3133C>T p.H1045Y | Missense Mutation (SNP) | VAF 49/193 reads (25%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs759422787; called by muse, mutect2, varscan2
- ARHGEF10L | c.1200G>A p.S400= | Splice Region (SNP) | VAF 37/139 reads (27%) | catalogued as rs538673823; called by muse, mutect2, varscan2
- ARID1A | c.671del p.P224Rfs*8 | Frame Shift Del (DEL) | VAF 15/57 reads (26%) | catalogued as rs1462224784; called by mutect2, pindel, varscan2
- ARNT | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 26/341 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs1238485591; called by muse, mutect2
- AVIL | c.94A>G p.S32G | Missense Mutation (SNP) | VAF 85/306 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.142); catalogued as rs1417618233; called by muse, mutect2, varscan2
- BCL11B | c.1349C>T p.T450M (on ENST00000357195 / NM_001282237.2; = p.T379M on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/311 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1453309074, COSV61737451; called by muse, mutect2, varscan2
- BICRA | c.4211C>T p.T1404M | Missense Mutation (SNP) | VAF 9/212 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1264919160; called by muse, mutect2
- BRINP3 | c.1511C>T p.T504M | Missense Mutation (SNP) | VAF 59/610 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.062); catalogued as rs1209013098, COSV66538570; called by muse, mutect2
- C1orf122 | c.268dup p.Q90Pfs*70 | Frame Shift Ins (INS) | VAF 26/202 reads (13%) | catalogued as rs747134922; called by mutect2, varscan2
- CACNA1S | c.2285C>T p.A762V | Missense Mutation (SNP) | VAF 144/593 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs867502946, COSV62945401; called by muse, mutect2, varscan2
- CCDC92 | c.801del p.I268Sfs*40 | Frame Shift Del (DEL) | VAF 24/161 reads (15%) | catalogued as rs773752200; called by mutect2, varscan2
- CDH26 | c.148C>T p.R50W | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as rs536661438, COSV54849684; called by muse, mutect2, varscan2
- CEL | c.1089G>A p.T363= (on ENST00000673714; = p.T360= on NM_001807.6) | Splice Region (SNP) | VAF 63/425 reads (15%) | catalogued as rs767182910; called by muse, mutect2, varscan2
- CEP170B | c.2495del p.P832Qfs*82 (on ENST00000453495; = p.P761Qfs*82 on NM_015005.3) | Frame Shift Del (DEL) | VAF 31/103 reads (30%) | catalogued as rs1566867656; called by mutect2, pindel, varscan2
- CEP350 | c.6184C>T p.R2062W | Missense Mutation (SNP) | VAF 29/212 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs370144436; called by muse, mutect2, varscan2
- CHSY1 | c.666del p.P223Lfs*3 | Frame Shift Del (DEL) | VAF 28/193 reads (15%) | catalogued as rs762321510; called by mutect2, pindel, varscan2
- CIC | c.3640C>T p.R1214* | Nonsense Mutation (SNP) | VAF 140/382 reads (37%) | catalogued as rs968289754, COSV50569160; called by muse, mutect2, varscan2
- CNMD | c.71del p.P24Rfs*6 | Frame Shift Del (DEL) | VAF 80/277 reads (29%) | catalogued as rs768157613; called by mutect2, pindel, varscan2
- CUX2 | c.2228C>G p.A743G | Missense Mutation (SNP) | VAF 30/203 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV99920433; called by muse, mutect2, varscan2
- CXorf21 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as COSV66763337; called by muse, mutect2, varscan2
- DAAM1 | c.667G>A p.V223M | Missense Mutation (SNP) | VAF 93/260 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759856885, CM154571, COSV100658513; called by muse, mutect2, varscan2
- DAB2IP | c.2042G>T p.G681V (on ENST00000408936; = p.G653V on NM_032552.3) | Missense Mutation (SNP) | VAF 9/228 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs960776359; called by muse, mutect2
- DCLRE1C | c.1124T>C p.L375P (on ENST00000378278 / NM_001350965.2; = p.L260P on NM_022487.4) | Missense Mutation (SNP) | VAF 101/523 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1386442094; called by muse, mutect2, varscan2
- DENND5A | c.2821G>A p.D941N | Missense Mutation (SNP) | VAF 51/202 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as rs755714912, COSV100064300; called by muse, mutect2, varscan2
- DGKK | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 60/210 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.015); catalogued as COSV65708402; called by muse, mutect2, varscan2
- DIDO1 | c.6358G>A p.G2120S | Missense Mutation (SNP) | VAF 106/363 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV56626190; called by muse, mutect2, varscan2
- DISP3 | c.1085C>T p.A362V | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99609634; called by muse, mutect2
- DLGAP2 | c.1664C>T p.A555V | Missense Mutation (SNP) | VAF 55/178 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV70103421; called by muse, mutect2, varscan2
- DLGAP2 | c.2465G>T p.R822L | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); catalogued as COSV101421035; called by muse, mutect2
- DLL4 | c.1138C>T p.R380C | Missense Mutation (SNP) | VAF 117/315 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs1268802700, COSV51063233; called by muse, mutect2, varscan2
- DMD | c.8490del p.Q2831Rfs*25 | Frame Shift Del (DEL) | VAF 111/370 reads (30%) | catalogued as COSV58912104; called by mutect2, pindel, varscan2
- DNAH17 | c.2482C>T p.R828C | Missense Mutation (SNP) | VAF 249/681 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as rs777090859, COSV67751492; called by muse, mutect2, varscan2
- DNAJB12 | c.733G>A p.G245S (on ENST00000338820; = p.G211S on NM_017626.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 92/216 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs752220148; called by muse, mutect2, varscan2
- DSTN | c.308del p.L103Cfs*6 | Frame Shift Del (DEL) | VAF 10/74 reads (14%) | catalogued as rs750962255; called by mutect2, varscan2
- EBP | c.650C>T p.T217M | Missense Mutation (SNP) | VAF 54/368 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs150348311; ClinVar: likely benign; called by muse, mutect2, varscan2
- EFCAB3 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as COSV59505134; called by muse, mutect2
- EOLA2 | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as rs1235153320, COSV62207238; called by muse, mutect2
- FAM184B | c.2941G>A p.A981T | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1433446644, COSV99401915; called by muse, mutect2
- FBN2 | c.921C>A p.H307Q | Missense Mutation (SNP) | VAF 259/345 reads (75%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.757); catalogued as COSV52525907; called by muse, mutect2, varscan2
- FUS | c.1129C>T p.R377W | Missense Mutation (SNP) | VAF 63/273 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); catalogued as rs766187715, CM141064, COSV54216477; called by muse, mutect2, varscan2
- GAMT | c.526del p.E176Sfs*2 | Frame Shift Del (DEL) | VAF 53/286 reads (19%) | catalogued as CD0911438; called by mutect2, pindel, varscan2
- GJB3 | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 112/410 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145247495; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPR101 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99981284; called by muse, mutect2, varscan2
- HCN4 | c.1814C>T p.T605M | Missense Mutation (SNP) | VAF 123/417 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1018484647, COSV56082458, COSV56086645; called by muse, mutect2, varscan2
- HCRTR2 | c.32del p.P11Lfs*11 | Frame Shift Del (DEL) | VAF 96/625 reads (15%) | catalogued as rs755844571, COSV63794110; called by mutect2, varscan2
- HDAC3 | c.1118C>A p.P373H | Missense Mutation (SNP) | VAF 21/326 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59495962; called by muse, mutect2
- HMCN1 | c.11995G>A p.V3999I | Missense Mutation (SNP) | VAF 65/347 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as rs182664406; called by muse, mutect2, varscan2
- HRNR | c.892C>T p.R298* | Nonsense Mutation (SNP) | VAF 102/919 reads (11%) | catalogued as rs1265802700, COSV100914013; called by muse, mutect2, varscan2
- HSD11B1L | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 12/357 reads (3%) | SIFT tolerated (0.54); PolyPhen benign (0.052); catalogued as rs868612654, COSV100028775; called by muse, mutect2
- ICAM3 | c.539G>A p.S180N | Missense Mutation (SNP) | VAF 158/594 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0.315); catalogued as rs747564030; called by muse, mutect2, varscan2
- IFT122 | c.1397A>G p.E466G (on ENST00000348417 / NM_052989.3; = p.E407G on NM_018262.4) | Missense Mutation (SNP) | VAF 99/568 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1289890903; called by muse, mutect2, varscan2
- IL27 | c.655C>T p.R219W | Missense Mutation (SNP) | VAF 24/430 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs373848919, COSV60494496; called by muse, mutect2
- IQGAP3 | c.3131G>A p.R1044H | Missense Mutation (SNP) | VAF 135/781 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs377284542; called by muse, mutect2, varscan2
- KCNC2 | c.385G>A p.V129M | Missense Mutation (SNP) | VAF 241/657 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV54372281; called by muse, mutect2, varscan2
- KEAP1 | c.1151C>A p.P384H | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.67); catalogued as COSV50658088; called by muse, mutect2, varscan2
- KIF1B | c.1280G>A p.R427H | Missense Mutation (SNP) | VAF 74/427 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as rs955206959; called by muse, mutect2, varscan2
- KLF14 | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 118/473 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60588753, COSV60588846; called by muse, mutect2, varscan2
- KRBA1 | c.2510G>A p.R837Q | Missense Mutation (SNP) | VAF 22/384 reads (6%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.997); catalogued as rs767583041, COSV55443871; called by muse, mutect2
- KRTAP5-10 | c.143G>A p.C48Y | Missense Mutation (SNP) | VAF 22/644 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.737); catalogued as rs1301849871; called by muse, mutect2
- KTI12 | c.130G>T p.E44* | Nonsense Mutation (SNP) | VAF 132/370 reads (36%) | catalogued as COSV100860237; called by muse, mutect2, varscan2
- LAMA3 | c.9505G>A p.V3169I (on ENST00000313654 / NM_198129.4; = p.V1560I on NM_000227.6) | Missense Mutation (SNP) | VAF 183/541 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs367725541, COSV99333801; called by muse, mutect2, varscan2
- LANCL3 | c.192del p.L65Ffs*129 | Frame Shift Del (DEL) | VAF 71/306 reads (23%) | catalogued as rs782221297; called by mutect2, pindel, varscan2
- LCMT1 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 45/233 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs751848262; called by muse, mutect2, varscan2
- LINGO1 | c.55dup p.L19Pfs*160 | Frame Shift Ins (INS) | VAF 6/52 reads (12%) | catalogued as rs1251049258; called by mutect2, pindel, varscan2
- LRIT2 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 29/436 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs376430517, COSV100928288; called by muse, mutect2
- LYST | c.4871A>G p.D1624G | Missense Mutation (SNP) | VAF 19/358 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as COSV101089855; called by muse, mutect2
- MACF1 | c.17798G>A p.S5933N (on ENST00000372915; = p.S3978N on NM_012090.5) | Missense Mutation (SNP) | VAF 109/405 reads (27%) | catalogued as rs1315393672; called by muse, mutect2, varscan2
- MAGEC1 | c.1480C>T p.L494F | Missense Mutation (SNP) | VAF 175/565 reads (31%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.622); catalogued as COSV99595409; called by muse, mutect2, varscan2
- MAGIX | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 26/189 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.804); catalogued as rs781836801; called by muse, mutect2, varscan2
- MAP1S | c.2929G>A p.V977I | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.106); catalogued as rs554296571, COSV100141181; called by muse, mutect2, varscan2
- MAPK8IP3 | c.679G>A p.V227M | Missense Mutation (SNP) | VAF 142/313 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs555012156, COSV51724065; called by muse, mutect2, varscan2
- MARCHF8 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 16/436 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.708); catalogued as rs576158640; called by muse, mutect2
- MAST3 | c.2074A>G p.T692A | Missense Mutation (SNP) | VAF 98/305 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs769093451; called by muse, mutect2, varscan2
- MDN1 | c.12102G>T p.Q4034H | Missense Mutation (SNP) | VAF 37/200 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as COSV65522597; called by muse, mutect2
- MECOM | c.2249G>T p.R750L (on ENST00000468789 / NM_001105078.4; = p.R938L on NM_004991.4) | Missense Mutation (SNP) | VAF 77/276 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52961254; called by muse, mutect2, varscan2
- MIB2 | c.400G>A p.V134M | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.072); catalogued as rs371938823; called by muse, mutect2, varscan2
- MICALL2 | c.2476G>T p.E826* | Nonsense Mutation (SNP) | VAF 29/361 reads (8%) | catalogued as COSV52515800; called by muse, mutect2
- MMP21 | c.414del p.R139Efs*38 | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | catalogued as rs1265476704; called by mutect2, pindel
- MTA1 | c.1178G>A p.C393Y | Missense Mutation (SNP) | VAF 11/210 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100495234; called by muse, mutect2
- MUC16 | c.26144C>T p.T8715I | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.889); catalogued as rs1319619574; called by muse, mutect2, varscan2
- MUC19 | c.669+1G>A p.X223_splice | Splice Site (SNP) | VAF 9/250 reads (4%) | catalogued as rs1490305467; called by muse, mutect2
- MUC5B | c.6189del p.S2064Pfs*27 | Frame Shift Del (DEL) | VAF 120/538 reads (22%) | catalogued as COSV71594697; called by mutect2, pindel, varscan2
- MUC5B | c.10627G>A p.A3543T | Missense Mutation (SNP) | VAF 39/876 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as COSV71596508; called by muse, mutect2
- MYH14 | c.2458C>T p.R820C | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs992550534, COSV51818610; called by muse, mutect2, varscan2
- MYT1L | c.2936C>T p.A979V | Missense Mutation (SNP) | VAF 57/379 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1335745153, COSV67701585; called by muse, mutect2, varscan2
- NAV3 | c.731del p.K244Sfs*26 | Frame Shift Del (DEL) | VAF 24/134 reads (18%) | catalogued as rs35319232; called by mutect2, pindel, varscan2
- NCOR2 | c.4267C>T p.R1423C | Missense Mutation (SNP) | VAF 19/288 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs1183274636; called by muse, mutect2
- NKAIN4 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 66/170 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs577285022; called by muse, varscan2
- NKX3-2 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 50/421 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs762739841; called by muse, mutect2, varscan2
- NPLOC4 | c.641C>T p.T214M | Missense Mutation (SNP) | VAF 16/294 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs922916633; called by muse, mutect2
- NUP98 | c.3983del p.N1328Tfs*89 (on ENST00000359171 / NM_001365126.1; = p.N1311Tfs*89 on NM_016320.5 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 58/358 reads (16%) | catalogued as rs1214420150; called by mutect2, varscan2
- OAT | c.992G>A p.R331Q | Missense Mutation (SNP) | VAF 38/580 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.125); catalogued as rs201504751; called by muse, mutect2
- OR10G4 | c.145G>A p.V49M | Missense Mutation (SNP) | VAF 37/265 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.081); catalogued as rs750183845; called by muse, mutect2, varscan2
- OR52N2 | c.305A>G p.Q102R | Missense Mutation (SNP) | VAF 9/167 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1483569276; called by muse, mutect2
- P4HA1 | c.1559G>A p.R520H | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as rs1171770367, COSV54965458; called by muse, mutect2, varscan2
- PARD3B | c.3271G>A p.A1091T (on ENST00000406610 / NM_001302769.2; = p.A1022T on NM_057177.7) | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs370015965, COSV104414951; called by muse, mutect2, varscan2
- PCDH10 | c.679del p.Q227Sfs*43 | Frame Shift Del (DEL) | VAF 41/116 reads (35%) | catalogued as COSV52090150; called by mutect2, pindel, varscan2
- PCDH8 | c.224G>T p.R75L | Missense Mutation (SNP) | VAF 92/249 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs1195035451, COSV100132117; called by muse, mutect2, varscan2
- PCDHGA1 | c.1675G>A p.A559T | Missense Mutation (SNP) | VAF 19/583 reads (3%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.014); catalogued as COSV65297029; called by muse, mutect2
- PCDHGB1 | c.1898C>T p.A633V | Missense Mutation (SNP) | VAF 22/635 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as COSV53959753; called by muse, mutect2
- PCLO | c.2404C>A p.P802T | Missense Mutation (SNP) | VAF 83/253 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.009); catalogued as rs1290239901; called by muse, mutect2, varscan2
- PDE6B | c.1807G>A p.G603S | Missense Mutation (SNP) | VAF 130/528 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as rs758617342; called by muse, mutect2, varscan2
- PDZD2 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 90/292 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1029396347, COSV56853334; called by muse, mutect2, varscan2
- PEX26 | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 263/763 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765734604; called by muse, mutect2, varscan2
- PIGB | c.840del p.F280Lfs*12 | Frame Shift Del (DEL) | VAF 60/172 reads (35%) | catalogued as rs756552559; called by mutect2, varscan2
- PIGN | c.2577-5del | Splice Region (DEL) | VAF 32/100 reads (32%) | catalogued as rs138671843; ClinVar: benign / likely benign; called by mutect2, varscan2
- PLCB2 | c.3113+7C>T | Splice Region (SNP) | VAF 35/340 reads (10%) | catalogued as rs762749326; called by muse, mutect2, varscan2
- PM20D2 | c.254C>T p.T85M | Missense Mutation (SNP) | VAF 18/304 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1420453391; called by muse, mutect2
- POTEA | c.164C>T p.T55M | Missense Mutation (SNP) | VAF 28/370 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.076); catalogued as rs751493528; called by muse, mutect2
- PPFIA4 | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 45/286 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs755139991, COSV55314426; called by muse, mutect2, varscan2
- PPP5C | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 32/313 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV50143747; called by muse, mutect2
- PRDM15 | c.1450G>A p.V484I | Missense Mutation (SNP) | VAF 69/445 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0.32); catalogued as rs1306042726; called by muse, mutect2, varscan2
- PRPF8 | c.5517G>T p.W1839C | Missense Mutation (SNP) | VAF 194/553 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59268573; called by muse, mutect2, varscan2
- PSCA | c.208G>A p.V70M | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as rs782260537, COSV56653352; called by muse, mutect2, varscan2
- PSKH2 | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 79/346 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV52612955; called by muse, mutect2, varscan2
- PTEN | c.388del p.R130Efs*4 | Frame Shift Del (DEL) | VAF 156/549 reads (28%) | catalogued as CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; called by mutect2, pindel, varscan2
- PTPRS | c.5321C>T p.T1774M | Missense Mutation (SNP) | VAF 77/227 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753489907; called by muse, mutect2, varscan2
- PXDNL | c.2488C>T p.R830W | Missense Mutation (SNP) | VAF 116/348 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as COSV100681368, COSV62494974; called by muse, mutect2
- RD3 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 46/502 reads (9%) | SIFT tolerated (0.97); PolyPhen benign (0.005); catalogued as COSV100879187, COSV65361821; called by muse, mutect2
- RIBC1 | c.802C>T p.R268W | Missense Mutation (SNP) | VAF 19/461 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as rs1380299601; called by muse, mutect2
- RNF213 | c.8353G>A p.A2785T | Missense Mutation (SNP) | VAF 114/320 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758896947, COSV60399100; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 90/314 reads (29%) | catalogued as rs755128667, COSV68457540; called by mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 74/258 reads (29%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RRAGA | c.183G>T p.W61C | Missense Mutation (SNP) | VAF 111/339 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65844130; called by muse, mutect2, varscan2
- RTL1 | c.2005C>T p.R669C | Missense Mutation (SNP) | VAF 51/326 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs1566753444; called by muse, mutect2, varscan2
- SALL3 | c.1124A>G p.N375S | Missense Mutation (SNP) | VAF 55/206 reads (27%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.991); catalogued as rs1291632598; called by muse, mutect2, varscan2
- SEMA5A | c.1915C>T p.R639C | Missense Mutation (SNP) | VAF 70/205 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101228520; called by muse, mutect2, varscan2
- SGSM1 | c.3404G>A p.R1135Q (on ENST00000400359 / NM_001039948.4; = p.R1074Q on NM_133454.3) | Missense Mutation (SNP) | VAF 16/466 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as COSV68514425; called by muse, mutect2
- SIGLEC1 | c.2140G>A p.A714T | Missense Mutation (SNP) | VAF 42/286 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1437851354; called by muse, mutect2, varscan2
- SKOR1 | c.2071G>A p.G691S | Missense Mutation (SNP) | VAF 15/264 reads (6%) | SIFT tolerated (0.93); PolyPhen benign (0.033); catalogued as rs982051327, COSV58245887; called by muse, mutect2
- SLC18A1 | c.1445del p.P482Rfs*10 | Frame Shift Del (DEL) | VAF 11/108 reads (10%) | catalogued as COSV99368642; called by mutect2, pindel
- SLC35E3 | c.103A>G p.I35V | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as rs371316093; called by muse, mutect2, varscan2
- SLC39A10 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 87/244 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs184343212; called by muse, mutect2, varscan2
- SLC4A3 | c.2652del p.S885Afs*22 | Frame Shift Del (DEL) | VAF 75/286 reads (26%) | catalogued as rs760972612; called by mutect2, pindel, varscan2
- SMC4 | c.1824del p.K608Nfs*15 | Frame Shift Del (DEL) | VAF 42/156 reads (27%) | catalogued as rs1038263749; called by mutect2, varscan2
- SNRPD1 | c.297_302del p.R114_G115del | In Frame Del (DEL) | VAF 68/267 reads (25%) | catalogued as rs753754262; called by mutect2, pindel, varscan2
- SOST | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 50/319 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs760682674, COSV100059856; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPATS2L | c.1505C>T p.P502L | Missense Mutation (SNP) | VAF 31/197 reads (16%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs778618948; called by muse, mutect2, varscan2
- SUDS3 | c.352C>T p.Q118* | Nonsense Mutation (SNP) | VAF 72/300 reads (24%) | catalogued as COSV66916147; called by muse, mutect2, varscan2
- SYT4 | c.811del p.M271Cfs*2 | Frame Shift Del (DEL) | VAF 28/112 reads (25%) | catalogued as COSV54902851; called by mutect2, pindel, varscan2
- TAFA5 | c.200G>A p.R67H (on ENST00000402357 / NM_001082967.3; = p.R60H on NM_015381.7) | Missense Mutation (SNP) | VAF 119/346 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769032022; called by muse, mutect2, varscan2
- TAFA5 | c.367G>A p.G123S (on ENST00000402357 / NM_001082967.3; = p.G116S on NM_015381.7) | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.406); catalogued as rs548972375, COSV60985354; called by muse, mutect2, varscan2
- TBX2 | c.1316C>T p.A439V | Missense Mutation (SNP) | VAF 103/386 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.063); catalogued as COSV99538733; called by muse, mutect2, varscan2
- TBX6 | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 35/238 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745709929; called by muse, mutect2, varscan2
- TCF7L2 | c.1604C>T p.S535L (on ENST00000355995 / NM_001367943.1; = p.S512L on NM_030756.5) | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs770242240; called by muse, mutect2, varscan2
- TDRD12 | c.1213G>A p.V405M | Missense Mutation (SNP) | VAF 73/229 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs558477595; called by muse, mutect2, varscan2
- TERF2 | c.943G>A p.A315T | Missense Mutation (SNP) | VAF 72/242 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as rs762832009, COSV54749232; called by muse, mutect2, varscan2
- TGM1 | c.1403-1G>T p.X468_splice | Splice Site (SNP) | VAF 18/594 reads (3%) | catalogued as rs1170353425; called by muse, mutect2
- TMEM120A | c.658C>T p.R220W | Missense Mutation (SNP) | VAF 17/340 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs888199370; called by muse, mutect2
- TMEM242 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs782344812; called by muse, mutect2, varscan2
- TNXB | c.8883G>A p.T2961= (on ENST00000647633; = p.T2714= on NM_019105.8 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 45/271 reads (17%) | catalogued as rs765368756; called by muse, mutect2, varscan2
- TOPAZ1 | c.1893dup p.A632Sfs*2 | Frame Shift Ins (INS) | VAF 50/146 reads (34%) | catalogued as rs753884819; called by mutect2, varscan2
- TRAM1L1 | c.905C>G p.S302W | Missense Mutation (SNP) | VAF 51/177 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs562701564, COSV60293190, COSV60293312; called by muse, mutect2, varscan2
- TRIM39 | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 93/542 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.912); catalogued as rs1420010316, COSV64956451; called by muse, mutect2, varscan2
- TRMU | c.480G>A p.A160= | Splice Region (SNP) | VAF 23/343 reads (7%) | catalogued as rs774025705; called by muse, mutect2
- USP31 | c.3719G>A p.R1240H | Missense Mutation (SNP) | VAF 76/292 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.791); catalogued as COSV54851999; called by muse, mutect2, varscan2
- VAV2 | c.2609C>T p.T870M (on ENST00000371850 / NM_001134398.2; = p.T831M on NM_003371.4) | Missense Mutation (SNP) | VAF 93/290 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143833447; called by muse, mutect2, varscan2
- VPS13B | c.6401T>A p.I2134N | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV62154201; called by muse, mutect2, varscan2
- WASL | c.387dup p.F130Ifs*17 | Frame Shift Ins (INS) | VAF 32/244 reads (13%) | catalogued as rs1191999623; called by mutect2, varscan2
- ZDHHC24 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 122/363 reads (34%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.57); catalogued as COSV100130663; called by muse, mutect2, varscan2
- ZFP64 | c.911C>T p.S304L | Missense Mutation (SNP) | VAF 96/360 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.284); catalogued as rs376200226; called by muse, mutect2, varscan2
- ZFPM1 | c.946G>A p.G316R | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1163227742; called by muse, mutect2, varscan2
- ZMYM4 | c.3475C>T p.R1159C | Missense Mutation (SNP) | VAF 49/319 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs760077258; called by muse, mutect2, varscan2
- ZNF497 | c.1130G>A p.R377Q | Missense Mutation (SNP) | VAF 82/298 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1456173350; called by muse, mutect2, varscan2
- ZNF560 | c.805A>G p.K269E | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs766994516; called by muse, mutect2, varscan2
- ZNF646 | c.2786G>A p.R929H | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs377644012; called by muse, mutect2, varscan2
- ABCA13 | c.14493G>C p.Q4831H | Missense Mutation (SNP) | VAF 17/206 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.046); called by muse, mutect2
- ACSS1 | c.892A>G p.T298A | Missense Mutation (SNP) | VAF 78/311 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACTG2 | c.255+3_255+4del p.X85_splice | Splice Site (DEL) | VAF 64/199 reads (32%) | called by mutect2, pindel, varscan2
- AMER1 | c.1088T>C p.V363A | Missense Mutation (SNP) | VAF 71/192 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ANKRD49 | c.635C>T p.A212V | Missense Mutation (SNP) | VAF 69/228 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); called by muse, mutect2, varscan2
- ANKRD50 | c.3778C>T p.P1260S | Missense Mutation (SNP) | VAF 74/207 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ANTKMT | c.641C>A p.P214H | Missense Mutation (SNP) | VAF 52/281 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- ARHGAP35 | c.4444del p.Q1482Sfs*317 | Frame Shift Del (DEL) | VAF 24/113 reads (21%) | called by mutect2, pindel, varscan2
- ARSB | c.1139T>G p.I380S | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- ASAP2 | c.2357del p.P786Rfs*25 | Frame Shift Del (DEL) | VAF 24/166 reads (14%) | called by mutect2, varscan2
- ASB7 | c.439A>G p.S147G | Missense Mutation (SNP) | VAF 25/410 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.112); called by muse, mutect2
- ATXN2L | c.701del p.G234Vfs*33 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | called by mutect2, pindel
- B4GALNT4 | c.190del p.V64Sfs*28 | Frame Shift Del (DEL) | VAF 69/262 reads (26%) | called by mutect2, varscan2
- BMP6 | c.1393G>A p.V465I | Missense Mutation (SNP) | VAF 77/250 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C8orf33 | c.348G>A p.W116* | Nonsense Mutation (SNP) | VAF 74/291 reads (25%) | called by muse, mutect2, varscan2
- CACNA1G | c.6830G>T p.S2277I | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- CAPN9 | c.1238C>T p.A413V | Missense Mutation (SNP) | VAF 50/202 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- CARMIL3 | c.3460G>T p.V1154F | Missense Mutation (SNP) | VAF 19/199 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2
- CASKIN2 | c.992C>T p.T331I | Missense Mutation (SNP) | VAF 23/385 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.462); called by muse, mutect2
- CASP1 | c.301A>G p.M101V | Missense Mutation (SNP) | VAF 9/166 reads (5%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2
- CBR1 | c.563G>A p.G188D | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); called by muse, mutect2, varscan2
- CCDC186 | c.1426-2A>G p.X476_splice | Splice Site (SNP) | VAF 8/156 reads (5%) | called by muse, mutect2
- CEP20 | c.426A>T p.Q142H | Missense Mutation (SNP) | VAF 75/190 reads (39%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CHAF1A | c.2702A>G p.Q901R | Missense Mutation (SNP) | VAF 10/250 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CHRNE | c.500+4G>T | Splice Region (SNP) | VAF 24/308 reads (8%) | called by muse, mutect2
- CLCN1 | c.2645C>A p.P882H | Missense Mutation (SNP) | VAF 83/226 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNNM4 | c.1951C>A p.R651S | Missense Mutation (SNP) | VAF 47/362 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- CNTNAP3 | c.2681A>G p.Q894R | Missense Mutation (SNP) | VAF 20/444 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.081); called by muse, mutect2
- CNTNAP3 | c.2090dup p.L698Tfs*10 | Frame Shift Ins (INS) | VAF 26/214 reads (12%) | called by mutect2, varscan2
- CPLANE1 | c.7801G>A p.V2601I | Missense Mutation (SNP) | VAF 55/166 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- CRB2 | c.1574T>C p.V525A | Missense Mutation (SNP) | VAF 15/332 reads (5%) | SIFT tolerated (0.98); PolyPhen benign (0); called by muse, mutect2
- CYP3A4 | c.647del p.L216Wfs*8 | Frame Shift Del (DEL) | VAF 95/322 reads (30%) | called by mutect2, pindel, varscan2
- CYTH3 | c.1049G>A p.R350H (on ENST00000396741; = p.R349H on NM_004227.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 73/194 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- DDX19B | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 50/210 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DLEU7 | c.215T>G p.V72G | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DNAH9 | c.9682T>C p.F3228L | Missense Mutation (SNP) | VAF 179/669 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- DNM1 | c.359T>C p.I120T | Missense Mutation (SNP) | VAF 51/156 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EP400 | c.4598del p.P1533Rfs*35 | Frame Shift Del (DEL) | VAF 48/286 reads (17%) | called by mutect2, pindel, varscan2
- EPHX2 | c.1548G>T p.R516S | Missense Mutation (SNP) | VAF 39/216 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ESRP1 | c.82_84del p.K28del | In Frame Del (DEL) | VAF 52/260 reads (20%) | called by mutect2, pindel, varscan2
- EVI2B | c.188G>A p.S63N | Missense Mutation (SNP) | VAF 13/368 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- FAM120C | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 117/487 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.407); called by muse, mutect2, varscan2
- FANCB | c.2052A>G p.I684M | Missense Mutation (SNP) | VAF 10/295 reads (3%) | SIFT tolerated (0.26); PolyPhen benign (0.006); called by muse, mutect2
- FAT4 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- FBN2 | c.4838C>T p.A1613V | Missense Mutation (SNP) | VAF 47/267 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- FCRL3 | c.791C>T p.T264I | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.2); called by muse, mutect2
- FGD5 | c.1076G>A p.S359N | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FIGNL2 | c.368G>A p.G123D | Missense Mutation (SNP) | VAF 73/490 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- FOXF1 | c.943C>T p.H315Y | Missense Mutation (SNP) | VAF 32/452 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.899); called by muse, mutect2
- G6PC3 | c.218+2T>C p.X73_splice | Splice Site (SNP) | VAF 50/492 reads (10%) | called by muse, mutect2
- GABRD | c.189del p.V64* | Frame Shift Del (DEL) | VAF 122/429 reads (28%) | called by mutect2, pindel, varscan2
- GARNL3 | c.2863A>G p.S955G | Missense Mutation (SNP) | VAF 9/191 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.026); called by muse, mutect2
- GCNA | c.965_994dup p.S322_D331dup | In Frame Ins (INS) | VAF 81/285 reads (28%) | called by muse*, mutect2
- GDNF | c.143G>A p.S48N | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by muse, mutect2
- GGNBP2 | c.1035del p.V346Yfs*20 | Frame Shift Del (DEL) | VAF 9/71 reads (13%) | called by mutect2, pindel, varscan2
- GLB1L | c.359C>A p.P120Q | Missense Mutation (SNP) | VAF 22/252 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GPR3 | c.296C>A p.A99D | Missense Mutation (SNP) | VAF 28/400 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.024); called by muse, mutect2
- HEATR3 | c.319A>G p.S107G | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- HIVEP3 | c.4033C>T p.Q1345* | Nonsense Mutation (SNP) | VAF 19/55 reads (35%) | called by muse, mutect2, varscan2
- HMCN2 | c.15109G>A p.V5037M | Missense Mutation (SNP) | VAF 8/135 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HTR2B | c.1001del p.L334Cfs*12 | Frame Shift Del (DEL) | VAF 64/221 reads (29%) | called by mutect2, pindel, varscan2
- INPP5B | c.2152T>C p.W718R (on ENST00000373023; = p.W638R on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- INVS | c.1906C>T p.Q636* | Nonsense Mutation (SNP) | VAF 182/719 reads (25%) | called by muse, mutect2, varscan2
- ITGA10 | c.1150-1G>T p.X384_splice | Splice Site (SNP) | VAF 12/279 reads (4%) | called by muse, mutect2
- KCNA6 | c.1315G>T p.G439C | Missense Mutation (SNP) | VAF 83/219 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNJ4 | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 148/361 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNK5 | c.1357del p.A453Lfs*7 | Frame Shift Del (DEL) | VAF 66/178 reads (37%) | called by mutect2, pindel
- KIAA1958 | c.462del p.D155Mfs*23 | Frame Shift Del (DEL) | VAF 42/146 reads (29%) | called by mutect2, pindel, varscan2
- KIR2DL3 | c.91C>A p.L31I | Missense Mutation (SNP) | VAF 42/480 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.357); called by muse, mutect2
- KMT2B | c.5636dup p.V1880Cfs*92 | Frame Shift Ins (INS) | VAF 53/252 reads (21%) | called by mutect2, pindel, varscan2
- KMT2C | c.576_577del p.G194Tfs*25 | Frame Shift Del (DEL) | VAF 75/232 reads (32%) | called by mutect2, pindel, varscan2
- KRT25 | c.599G>T p.R200I | Missense Mutation (SNP) | VAF 85/250 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- KRTAP10-5 | c.501del p.C168Afs*201 | Frame Shift Del (DEL) | VAF 115/866 reads (13%) | called by mutect2, pindel, varscan2
- KTN1 | c.3941del p.P1314Qfs*13 (on ENST00000395314 / NM_001271014.2; = p.P1257Qfs*13 on NM_004986.4) | Frame Shift Del (DEL) | VAF 28/194 reads (14%) | called by mutect2, pindel, varscan2
- LAMA4 | c.788del p.P263Lfs*9 (on ENST00000230538 / NM_001105206.3; = p.P263Lfs*11 on NM_002290.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 51/324 reads (16%) | called by mutect2, pindel, varscan2
- LARGE2 | c.173del p.P58Qfs*59 | Frame Shift Del (DEL) | VAF 20/92 reads (22%) | called by mutect2, pindel, varscan2
- LHX2 | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 36/601 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- LMTK2 | c.3735G>T p.K1245N | Missense Mutation (SNP) | VAF 95/216 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- LRCH2 | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- LRRC8C | c.1855C>A p.L619M | Missense Mutation (SNP) | VAF 35/199 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LSM14B | c.1000_1002del p.T334del | In Frame Del (DEL) | VAF 34/162 reads (21%) | called by pindel, varscan2
- LTB4R | c.30del p.S11Hfs*2 | Frame Shift Del (DEL) | VAF 18/124 reads (15%) | called by mutect2, pindel, varscan2
- LTBP1 | c.4670C>T p.A1557V (on ENST00000404816 / NM_206943.4; = p.A1231V on NM_000627.4) | Missense Mutation (SNP) | VAF 15/296 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- MAD1L1 | c.1108C>A p.Q370K | Missense Mutation (SNP) | VAF 66/168 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MBOAT1 | c.513_515del p.Q171del | In Frame Del (DEL) | VAF 20/119 reads (17%) | called by pindel, varscan2
- MED27 | c.26T>C p.V9A | Missense Mutation (SNP) | VAF 45/344 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.104); called by muse, varscan2
- MID2 | c.1726G>T p.G576W | Missense Mutation (SNP) | VAF 39/348 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MYO16 | c.4153C>T p.R1385C | Missense Mutation (SNP) | VAF 16/295 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.27); called by muse, mutect2
- MYO1C | c.2233T>C p.W745R (on ENST00000648651 / NM_001080779.2; = p.W710R on NM_033375.5) | Missense Mutation (SNP) | VAF 195/742 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- MYO7B | c.4184A>G p.Q1395R | Missense Mutation (SNP) | VAF 27/455 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.554); called by muse, mutect2
- NAV1 | c.5137C>G p.L1713V | Missense Mutation (SNP) | VAF 15/518 reads (3%) | SIFT tolerated (0.91); PolyPhen benign (0.061); called by muse, mutect2
- NCOR1 | c.1573dup p.T525Nfs*11 | Frame Shift Ins (INS) | VAF 21/84 reads (25%) | called by mutect2, pindel, varscan2
- NFASC | c.494del p.P165Rfs*12 (on ENST00000339876 / NM_001378329.1; = p.P159Rfs*12 on NM_015090.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 82/449 reads (18%) | called by mutect2, pindel, varscan2
- NFASC | c.1235dup p.N412Kfs*55 (on ENST00000339876 / NM_001378329.1; = p.N423Kfs*55 on NM_015090.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 41/382 reads (11%) | called by mutect2, pindel, varscan2
- NMT2 | c.180T>A p.N60K | Missense Mutation (SNP) | VAF 38/332 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NOC4L | c.1516G>T p.G506C | Missense Mutation (SNP) | VAF 19/230 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.43); called by muse, mutect2
- NOX4 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NPAS2 | c.104T>C p.M35T | Missense Mutation (SNP) | VAF 24/174 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NPAS3 | c.647del p.P216Lfs*38 (on ENST00000356141 / NM_001164749.2; = p.P184Lfs*38 on NM_022123.3) | Frame Shift Del (DEL) | VAF 70/224 reads (31%) | called by mutect2, varscan2
- NPHP3 | c.2468A>G p.H823R | Missense Mutation (SNP) | VAF 14/281 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.036); called by muse, mutect2
- OR51T1 | c.211G>T p.V71F | Missense Mutation (SNP) | VAF 35/208 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- OR8D2 | c.358T>C p.Y120H | Missense Mutation (SNP) | VAF 50/215 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OSBPL1A | c.1319del p.N440Tfs*18 | Frame Shift Del (DEL) | VAF 34/256 reads (13%) | called by mutect2, pindel, varscan2
- OTOG | c.5996C>T p.A1999V | Missense Mutation (SNP) | VAF 153/533 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- OTOGL | c.1641dup p.N548* (on ENST00000547103; = p.N539* on NM_173591.4 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 35/157 reads (22%) | called by mutect2, pindel, varscan2
- PCDHA12 | c.558del p.D187Ifs*8 | Frame Shift Del (DEL) | VAF 79/256 reads (31%) | called by mutect2, pindel, varscan2
- PCDHB1 | c.745G>T p.A249S | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); called by muse, mutect2
- PCNT | c.1306T>C p.F436L | Missense Mutation (SNP) | VAF 92/590 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDCD1LG2 | c.770_771del p.T257Nfs*26 | Frame Shift Del (DEL) | VAF 36/154 reads (23%) | called by pindel, varscan2
- PDCD6IP | c.265-5T>C | Splice Region (SNP) | VAF 12/170 reads (7%) | called by muse, mutect2
- PDE4DIP | c.908T>C p.V303A | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- PDS5A | c.3142G>A p.A1048T | Missense Mutation (SNP) | VAF 18/221 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.69); called by muse, mutect2
- PHF14 | c.546del p.K182Nfs*19 | Frame Shift Del (DEL) | VAF 37/230 reads (16%) | called by mutect2, pindel, varscan2
- PLEC | c.11603G>A p.G3868D (on ENST00000322810 / NM_201380.4; = p.G3758D on NM_000445.5) | Missense Mutation (SNP) | VAF 17/458 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- PLXNA2 | c.734A>G p.Y245C | Missense Mutation (SNP) | VAF 31/790 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PPCS | c.735G>T p.K245N | Missense Mutation (SNP) | VAF 16/498 reads (3%) | SIFT tolerated (0.7); PolyPhen benign (0.003); called by muse, mutect2
- PPFIA4 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 116/392 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- PPME1 | c.818A>G p.K273R | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- PRICKLE2 | c.1793del p.G598Afs*40 (on ENST00000295902; = p.G542Afs*40 on NM_198859.4) | Frame Shift Del (DEL) | VAF 79/226 reads (35%) | called by mutect2, pindel, varscan2
- PRPF40B | c.605del p.P202Hfs*86 (on ENST00000380281; = p.P196Hfs*86 on NM_012272.3) | Frame Shift Del (DEL) | VAF 49/227 reads (22%) | called by mutect2, pindel, varscan2
- PSMD1 | c.372del p.K124Nfs*11 | Frame Shift Del (DEL) | VAF 23/126 reads (18%) | called by mutect2, varscan2
- PSMF1 | c.104A>G p.Y35C | Missense Mutation (SNP) | VAF 15/174 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.375); called by muse, mutect2
- PTEN | c.954dup p.T319Yfs*6 | Frame Shift Ins (INS) | VAF 75/259 reads (29%) | called by mutect2, pindel, varscan2
- PTPRM | c.4170-2A>G p.X1390_splice | Splice Site (SNP) | VAF 20/103 reads (19%) | called by muse, mutect2, varscan2
- PXYLP1 | c.511G>A p.V171M | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- RANBP2 | c.1144C>T p.Q382* | Nonsense Mutation (SNP) | VAF 136/637 reads (21%) | called by muse, mutect2, varscan2
- RDX | c.1620T>G p.D540E | Missense Mutation (SNP) | VAF 161/439 reads (37%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- RNF128 | c.594del p.K198Nfs*6 (on ENST00000255499 / NM_194463.2; = p.K172Nfs*6 on NM_024539.3) | Frame Shift Del (DEL) | VAF 45/370 reads (12%) | called by mutect2, pindel, varscan2
- RNPEPL1 | c.2093_2094del p.T698Rfs*34 | Frame Shift Del (DEL) | VAF 36/175 reads (21%) | called by pindel, varscan2
- RS1 | c.199A>G p.K67E | Missense Mutation (SNP) | VAF 36/521 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.473); called by muse, mutect2
- RYR3 | c.1361A>G p.E454G | Missense Mutation (SNP) | VAF 17/236 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- SCAI | c.565T>C p.C189R (on ENST00000336505 / NM_001144877.3; = p.C212R on NM_173690.5) | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- SCML4 | c.784C>T p.H262Y | Missense Mutation (SNP) | VAF 18/306 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- SCN8A | c.5021C>T p.A1674V | Missense Mutation (SNP) | VAF 78/267 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- SEPHS1 | c.68T>C p.F23S | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- SFTPB | c.353A>G p.D118G | Missense Mutation (SNP) | VAF 15/256 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.113); called by muse, mutect2
- SHISA2 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 22/354 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.119); called by muse, mutect2
- SLC17A2 | c.240G>T p.K80N | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.039); called by muse, mutect2
- SLC22A31 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 71/197 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- SLC2A2 | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 21/518 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); called by muse, mutect2
- SLC35A2 | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 133/406 reads (33%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); called by muse, varscan2
- SLC35C2 | c.645_646del p.F216Cfs*4 | Frame Shift Del (DEL) | VAF 23/250 reads (9%) | called by pindel, varscan2
- SLC39A10 | c.839T>C p.V280A | Missense Mutation (SNP) | VAF 29/186 reads (16%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC9A5 | c.2321A>G p.Y774C | Missense Mutation (SNP) | VAF 41/231 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC9A9 | c.89del p.L30Cfs*7 | Frame Shift Del (DEL) | VAF 59/211 reads (28%) | called by mutect2, pindel, varscan2
- SOCS7 | c.1609G>T p.E537* | Nonsense Mutation (SNP) | VAF 10/266 reads (4%) | called by muse, mutect2
- SPTBN5 | c.3243G>T p.Q1081H | Missense Mutation (SNP) | VAF 20/332 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.085); called by muse, mutect2
- SRRM3 | c.689A>G p.K230R | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SSR3 | c.523G>A p.G175R | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STARD9 | c.506del p.K169Sfs*24 | Frame Shift Del (DEL) | VAF 25/146 reads (17%) | called by mutect2, pindel, varscan2
- STAT1 | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 30/464 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); called by muse, mutect2
- STK10 | c.9dup p.A4Cfs*21 | Frame Shift Ins (INS) | VAF 52/203 reads (26%) | called by mutect2, pindel
- STYXL2 | c.223dup p.V75Gfs*15 | Frame Shift Ins (INS) | VAF 52/296 reads (18%) | called by mutect2, pindel
- SVEP1 | c.6469G>A p.A2157T | Missense Mutation (SNP) | VAF 50/180 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- TBX18 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 110/271 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TNRC6A | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- TRAPPC10 | c.2152del p.V718Wfs*10 | Frame Shift Del (DEL) | VAF 127/411 reads (31%) | called by mutect2, pindel, varscan2
- TRAPPC8 | c.1336G>A p.A446T | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- TRIM7 | c.1364G>A p.C455Y | Missense Mutation (SNP) | VAF 23/242 reads (10%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.69); called by muse, mutect2
- TRIM7 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 109/146 reads (75%) | SIFT deleterious (0.05); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- TTC37 | c.3218-1G>A p.X1073_splice | Splice Site (SNP) | VAF 12/400 reads (3%) | called by muse, mutect2
- TTN | c.89842G>A p.A29948T (on ENST00000591111; = p.A22524T on NM_003319.4) | Missense Mutation (SNP) | VAF 7/106 reads (7%) | PolyPhen probably damaging (0.935); called by muse, mutect2
- UBE2O | c.2918T>C p.I973T | Missense Mutation (SNP) | VAF 60/171 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- UGT1A10 | c.208C>A p.L70M | Missense Mutation (SNP) | VAF 11/237 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.824); called by muse, mutect2
- UNC93A | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 60/399 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- USP27X | c.1042_1045del p.N348Dfs*75 | Frame Shift Del (DEL) | VAF 109/430 reads (25%) | called by pindel, varscan2
- USP34 | c.9558dup p.K3187Qfs*5 | Frame Shift Ins (INS) | VAF 38/190 reads (20%) | called by mutect2, pindel, varscan2
- UTP14A | c.1781T>C p.M594T | Missense Mutation (SNP) | VAF 55/355 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- VBP1 | c.26G>A p.G9D | Missense Mutation (SNP) | VAF 64/231 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- VGF | c.705G>A p.M235I | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- VPS35L | c.1138C>A p.Q380K | Missense Mutation (SNP) | VAF 46/265 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- WFDC1 | c.589T>C p.Y197H | Missense Mutation (SNP) | VAF 70/206 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- XK | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 55/483 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- ZBTB7B | c.750_756del p.G251Afs*62 (on ENST00000292176; = p.G285Afs*62 on NM_001252406.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 28/53 reads (53%) | called by mutect2, pindel, varscan2
- ZFAND5 | c.542C>T p.S181F | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF132 | c.1711T>C p.Y571H | Missense Mutation (SNP) | VAF 79/231 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- ZNF536 | c.1720T>C p.S574P | Missense Mutation (SNP) | VAF 100/313 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF561 | c.34del p.S12Pfs*14 | Frame Shift Del (DEL) | VAF 40/184 reads (22%) | called by mutect2, pindel, varscan2
- ZSWIM4 | c.2358G>T p.E786D | Missense Mutation (SNP) | VAF 34/627 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.646); called by muse, mutect2
- AC024598.1 | c.942C>T p.G314= | Silent (SNP) | VAF 26/252 reads (10%) | catalogued as rs1156349778; called by muse, mutect2, varscan2
- ACTN2 | c.762C>T p.H254= | Silent (SNP) | VAF 496/899 reads (55%) | catalogued as rs397516584, COSV63971828; ClinVar: likely benign; called by muse, mutect2, varscan2
- ADAP1 | c.108G>A p.L36= | Silent (SNP) | VAF 74/231 reads (32%) | called by muse, mutect2, varscan2
- ADGRA2 | c.319C>T p.L107= | Silent (SNP) | VAF 42/212 reads (20%) | called by muse, varscan2
- ADGRG7 | c.2340G>A p.P780= | Silent (SNP) | VAF 32/309 reads (10%) | catalogued as rs576939356; called by muse, mutect2, varscan2
- AGAP1 | c.2307C>G p.G769= (on ENST00000304032 / NM_001037131.3; = p.G716= on NM_014914.5) | Silent (SNP) | VAF 14/497 reads (3%) | catalogued as COSV58331803; called by muse, mutect2
- AHNAK2 | c.16473A>G p.S5491= | Silent (SNP) | VAF 29/341 reads (9%) | called by muse, mutect2
- AMELX | c.561G>A p.R187= | Silent (SNP) | VAF 143/528 reads (27%) | called by muse, mutect2, varscan2
- ANKRD35 | c.2610G>A p.L870= | Silent (SNP) | VAF 49/294 reads (17%) | called by muse, mutect2, varscan2
- APC2 | c.1593G>A p.A531= | Silent (SNP) | VAF 54/324 reads (17%) | catalogued as rs760400612; called by muse, mutect2, varscan2
- APOL1 | c.1062C>T p.Y354= | Silent (SNP) | VAF 58/238 reads (24%) | catalogued as rs760511001, COSV59868692; called by muse, mutect2, varscan2
- AR | c.153C>T p.G51= | Silent (SNP) | VAF 110/386 reads (28%) | catalogued as CD015304, COSV101017863; called by muse, varscan2
- ASB8 | c.826C>T p.L276= | Silent (SNP) | VAF 81/255 reads (32%) | called by muse, mutect2, varscan2
- ASGR2 | c.267G>A p.L89= | Silent (SNP) | VAF 26/155 reads (17%) | called by muse, mutect2, varscan2
- ASXL1 | c.2592C>T p.D864= | Silent (SNP) | VAF 27/448 reads (6%) | catalogued as rs147278940; called by muse, mutect2
- BAHCC1 | c.3768C>T p.D1256= | Silent (SNP) | VAF 18/411 reads (4%) | catalogued as rs369730574; called by muse, mutect2
- BCL11B | c.783G>A p.P261= (on ENST00000357195 / NM_001282237.2; = p.P190= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 47/182 reads (26%) | catalogued as rs1180451023; called by muse, mutect2, varscan2
- BPIFB2 | c.906G>A p.P302= | Silent (SNP) | VAF 101/283 reads (36%) | catalogued as rs768353960; called by muse, mutect2, varscan2
- CADPS | c.3459C>T p.S1153= | Silent (SNP) | VAF 12/158 reads (8%) | called by muse, mutect2
- CBY2 | c.216G>A p.A72= | Silent (SNP) | VAF 72/185 reads (39%) | catalogued as rs569033347; called by muse, mutect2, varscan2
- CBY2 | c.402C>A p.R134= | Silent (SNP) | VAF 138/401 reads (34%) | catalogued as COSV60119615; called by muse, mutect2, varscan2
- CCDC7 | c.2859C>T p.S953= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as rs373078675; called by muse, mutect2, varscan2
- CCNT2 | c.474A>G p.K158= | Silent (SNP) | VAF 27/167 reads (16%) | called by muse, mutect2, varscan2
- CDH15 | c.297G>A p.K99= | Silent (SNP) | VAF 152/646 reads (24%) | called by muse, mutect2, varscan2
- CMTM3 | c.276G>A p.K92= | Silent (SNP) | VAF 18/340 reads (5%) | catalogued as rs1487128353; called by muse, mutect2
- CROCC | c.1563C>T p.L521= | Silent (SNP) | VAF 13/114 reads (11%) | catalogued as rs761889666; called by muse, mutect2
- CYP1B1 | c.657C>T p.P219= | Silent (SNP) | VAF 86/289 reads (30%) | called by muse, mutect2, varscan2
- DDX42 | c.2277C>T p.A759= | Silent (SNP) | VAF 22/303 reads (7%) | catalogued as rs777054756; called by muse, mutect2
- DEPTOR | c.1086C>T p.A362= | Silent (SNP) | VAF 81/280 reads (29%) | catalogued as rs370014084; called by muse, mutect2, varscan2
- DIPK2B | c.531G>A p.S177= | Silent (SNP) | VAF 43/142 reads (30%) | catalogued as rs774573891; called by muse, varscan2
- DNASE1L2 | c.258T>C p.F86= | Silent (SNP) | VAF 34/431 reads (8%) | called by muse, mutect2
- DPEP3 | c.96C>T p.P32= | Silent (SNP) | VAF 104/413 reads (25%) | catalogued as rs1425325280, COSV99262562; called by muse, mutect2, varscan2
- DYSF | c.1518A>C p.S506= | Silent (SNP) | VAF 42/250 reads (17%) | called by muse, mutect2, varscan2
- EEPD1 | c.741C>T p.S247= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as rs200979746; called by muse, mutect2, varscan2
- EPS8L2 | c.357G>A p.T119= | Silent (SNP) | VAF 18/414 reads (4%) | catalogued as rs1195952801, COSV100585463; called by muse, mutect2
- EVA1B | c.258G>A p.V86= | Silent (SNP) | VAF 188/684 reads (27%) | catalogued as rs1169384015; called by muse, mutect2, varscan2
- FAM170A | c.624C>T p.T208= | Silent (SNP) | VAF 233/310 reads (75%) | catalogued as rs376653030; called by muse, mutect2, varscan2
- FOXRED2 | c.987C>A p.R329= | Silent (SNP) | VAF 20/308 reads (6%) | catalogued as COSV99340994; called by muse, mutect2
- FREM3 | c.834C>T p.D278= | Silent (SNP) | VAF 45/304 reads (15%) | called by muse, mutect2, varscan2
- GCM2 | c.240G>A p.S80= | Silent (SNP) | VAF 287/780 reads (37%) | catalogued as rs754771998; called by muse, mutect2, varscan2
- GGT6 | c.1134G>A p.L378= (on ENST00000574154 / NM_001122890.3; = p.L346= on NM_153338.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 98/330 reads (30%) | called by muse, mutect2, varscan2
- GIMAP4 | c.633C>T p.R211= | Silent (SNP) | VAF 76/247 reads (31%) | catalogued as rs1357201397, COSV55431998; called by muse, mutect2, varscan2
- GMEB2 | c.1089T>C p.R363= | Silent (SNP) | VAF 43/104 reads (41%) | called by muse, mutect2, varscan2
- GNB3 | c.750C>T p.C250= | Silent (SNP) | VAF 14/295 reads (5%) | catalogued as COSV57529817; called by muse, mutect2
- GRM4 | c.138T>C p.D46= | Silent (SNP) | VAF 53/234 reads (23%) | called by muse, mutect2, varscan2
- HIGD2B | c.141G>A p.P47= | Silent (SNP) | VAF 176/503 reads (35%) | catalogued as rs762583654; called by muse, mutect2, varscan2
- HOMER3 | c.751C>T p.L251= | Silent (SNP) | VAF 17/150 reads (11%) | called by muse, mutect2, varscan2
- HOXC11 | c.57C>T p.G19= | Silent (SNP) | VAF 73/205 reads (36%) | catalogued as rs146084910; called by muse, mutect2, varscan2
- HTR1E | c.996C>T p.L332= | Silent (SNP) | VAF 12/211 reads (6%) | catalogued as rs1056270836; called by muse, mutect2
- IRX4 | c.1401C>T p.P467= | Silent (SNP) | VAF 14/190 reads (7%) | called by muse, mutect2
- KLHL40 | c.669C>T p.S223= | Silent (SNP) | VAF 68/169 reads (40%) | catalogued as COSV99825847; called by muse, mutect2, varscan2
- KLHL5 | c.444T>C p.G148= | Silent (SNP) | VAF 107/277 reads (39%) | called by muse, mutect2, varscan2
- KPNA7 | c.1449G>A p.E483= | Silent (SNP) | VAF 58/180 reads (32%) | called by muse, mutect2, varscan2
- KRT82 | c.552C>T p.S184= | Silent (SNP) | VAF 85/344 reads (25%) | catalogued as rs144174481; called by muse, mutect2, varscan2
- KRTAP29-1 | c.333G>T p.S111= | Silent (SNP) | VAF 27/362 reads (7%) | called by muse, mutect2
- LILRB4 | c.786C>T p.I262= | Silent (SNP) | VAF 83/480 reads (17%) | catalogued as rs145072607; called by muse, mutect2, varscan2
- LMOD1 | c.1164C>A p.T388= | Silent (SNP) | VAF 167/962 reads (17%) | called by muse, mutect2, varscan2
- LMX1A | c.60C>A p.S20= | Silent (SNP) | VAF 68/388 reads (18%) | catalogued as rs1448470104, COSV54216572; called by muse, mutect2, varscan2
- LRFN1 | c.1452G>A p.A484= | Silent (SNP) | VAF 10/160 reads (6%) | catalogued as rs1316009211; called by muse, mutect2
- LRRC70 | c.567C>T p.N189= | Silent (SNP) | VAF 14/472 reads (3%) | called by muse, mutect2
- MACC1 | c.2388T>C p.S796= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as rs772846637, COSV60545359; called by muse, mutect2, varscan2
- MAP3K14 | c.1722C>T p.D574= | Silent (SNP) | VAF 102/411 reads (25%) | catalogued as rs755439399; called by muse, mutect2, varscan2
- MCOLN2 | c.1216C>T p.L406= | Silent (SNP) | VAF 36/153 reads (24%) | called by muse, mutect2, varscan2
- MYH10 | c.486C>T p.Y162= | Silent (SNP) | VAF 9/87 reads (10%) | catalogued as rs756950714; called by muse, mutect2, varscan2
- MYH4 | c.1548C>T p.F516= | Silent (SNP) | VAF 216/571 reads (38%) | catalogued as rs769124122, COSV55112661; called by muse, mutect2, varscan2
- MYH7B | c.5340G>A p.A1780= | Silent (SNP) | VAF 83/490 reads (17%) | catalogued as rs756255803, COSV52679871; called by muse, mutect2, varscan2
- MYLK3 | c.867G>C p.S289= | Silent (SNP) | VAF 17/410 reads (4%) | called by muse, mutect2
- MYRFL | c.1804A>C p.R602= | Silent (SNP) | VAF 70/210 reads (33%) | called by muse, mutect2, varscan2
- NCAPG2 | c.2046T>C p.A682= | Silent (SNP) | VAF 29/134 reads (22%) | catalogued as rs1480844137; called by muse, mutect2, varscan2
- NDN | c.765G>A p.P255= | Silent (SNP) | VAF 33/102 reads (32%) | catalogued as rs1169927556, COSV59361656; called by muse, mutect2, varscan2
- NEK1 | c.2562A>G p.Q854= | Silent (SNP) | VAF 53/170 reads (31%) | called by muse, mutect2, varscan2
- NEURL1 | c.912C>T p.H304= | Silent (SNP) | VAF 7/149 reads (5%) | called by muse, mutect2
- NSMF | c.168C>T p.D56= | Silent (SNP) | VAF 138/384 reads (36%) | catalogued as rs1212270662; called by muse, varscan2
- NTF3 | c.345G>A p.P115= | Silent (SNP) | VAF 95/251 reads (38%) | catalogued as rs772851614, COSV58417151; called by muse, mutect2, varscan2
- OBI1 | c.159A>G p.P53= | Silent (SNP) | VAF 84/224 reads (38%) | called by muse, mutect2, varscan2
- OR2W1 | c.468T>C p.S156= | Silent (SNP) | VAF 66/217 reads (30%) | called by muse, mutect2, varscan2
- OSBP2 | c.1497C>T p.L499= | Silent (SNP) | VAF 53/295 reads (18%) | catalogued as rs747343327; called by muse, mutect2, varscan2
- PAIP1 | c.60C>T p.G20= | Silent (SNP) | VAF 19/75 reads (25%) | called by muse, mutect2, varscan2
- POTEE | c.474C>T p.I158= | Silent (SNP) | VAF 186/712 reads (26%) | catalogued as rs142484775, COSV58227108; called by muse, varscan2
- PPRC1 | c.4341G>A p.S1447= | Silent (SNP) | VAF 102/255 reads (40%) | catalogued as rs769884934; called by muse, mutect2, varscan2
- PRKACA | c.808C>T p.L270= | Silent (SNP) | VAF 54/195 reads (28%) | called by muse, mutect2, varscan2
- PTPRN2 | c.1326C>T p.A442= | Silent (SNP) | VAF 89/242 reads (37%) | catalogued as rs373425856; called by muse, mutect2, varscan2
- PTPRS | c.4806C>T p.I1602= | Silent (SNP) | VAF 72/231 reads (31%) | catalogued as rs115634987; called by muse, mutect2, varscan2
- PYHIN1 | c.537C>T p.P179= | Silent (SNP) | VAF 52/178 reads (29%) | called by muse, mutect2, varscan2
- RERE | c.3348G>A p.P1116= | Silent (SNP) | VAF 17/154 reads (11%) | catalogued as rs754887260; called by muse, mutect2, varscan2
- RYR1 | c.5517G>A p.V1839= | Silent (SNP) | VAF 49/232 reads (21%) | called by muse, mutect2, varscan2
- SACM1L | c.954G>A p.E318= | Silent (SNP) | VAF 38/141 reads (27%) | called by muse, mutect2, varscan2
- SGCZ | c.264G>A p.K88= | Silent (SNP) | VAF 73/211 reads (35%) | catalogued as rs757463731; called by muse, mutect2, varscan2
- SLC12A2 | c.2058T>C p.Y686= | Silent (SNP) | VAF 13/357 reads (4%) | called by muse, mutect2
- SLC25A12 | c.1056C>A p.T352= | Silent (SNP) | VAF 41/419 reads (10%) | called by muse, mutect2
- SLC5A8 | c.1185G>A p.L395= | Silent (SNP) | VAF 40/467 reads (9%) | called by muse, mutect2
- SMIM1 | c.9C>A p.P3= | Silent (SNP) | VAF 52/148 reads (35%) | called by muse, mutect2, varscan2
- SPATA6L | c.261A>G p.T87= | Silent (SNP) | VAF 56/211 reads (27%) | catalogued as rs773649352; called by muse, mutect2, varscan2
- SSU72 | c.570C>T p.T190= | Silent (SNP) | VAF 116/312 reads (37%) | catalogued as rs376265266; called by muse, mutect2, varscan2
- STAB1 | c.2856G>A p.R952= | Silent (SNP) | VAF 36/201 reads (18%) | catalogued as rs778551877; called by muse, mutect2, varscan2
- TAF1L | c.1239T>C p.T413= | Silent (SNP) | VAF 95/606 reads (16%) | catalogued as rs1448567686; called by muse, mutect2, varscan2
- TAS2R60 | c.531T>C p.P177= | Silent (SNP) | VAF 47/272 reads (17%) | called by muse, mutect2, varscan2
- THOP1 | c.1509G>A p.A503= | Silent (SNP) | VAF 22/326 reads (7%) | catalogued as rs146626585; called by muse, mutect2
- THSD4 | c.210C>T p.S70= | Silent (SNP) | VAF 8/132 reads (6%) | called by muse, mutect2
- TMEM88 | c.15C>T p.P5= | Silent (SNP) | VAF 22/248 reads (9%) | catalogued as rs1374201803, COSV54684693; called by muse, mutect2
- TOGARAM1 | c.3018G>A p.T1006= | Silent (SNP) | VAF 128/337 reads (38%) | catalogued as rs1487104487; called by muse, mutect2, varscan2
- TPCN2 | c.2043G>A p.S681= | Silent (SNP) | VAF 87/299 reads (29%) | catalogued as rs548729497; called by muse, mutect2, varscan2
- TRIM37 | c.2706C>T p.S902= | Silent (SNP) | VAF 84/252 reads (33%) | catalogued as rs771485008, COSV51882416; called by muse, mutect2, varscan2
- TRIM48 | c.388C>T p.L130= | Silent (SNP) | VAF 87/584 reads (15%) | catalogued as COSV70162920; called by muse, mutect2, varscan2
- TTN | c.27897T>C p.S9299= (on ENST00000591111; = p.S8372= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 62/194 reads (32%) | called by muse, mutect2, varscan2
- TTN | c.8937C>T p.N2979= (on ENST00000591111; = p.N2933= on NM_003319.4) | Silent (SNP) | VAF 28/340 reads (8%) | catalogued as rs368525666; ClinVar: likely benign; called by muse, mutect2
- UHMK1 | c.1227C>T p.Y409= | Silent (SNP) | VAF 43/333 reads (13%) | called by muse, mutect2, varscan2
- USP15 | c.807C>T p.T269= (on ENST00000280377 / NM_001351159.2; = p.T240= on NM_006313.3 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 24/133 reads (18%) | catalogued as rs893626202, COSV54791256; called by muse, mutect2, varscan2
- VANGL2 | c.1329G>A p.A443= | Silent (SNP) | VAF 32/666 reads (5%) | catalogued as rs146767141; called by muse, mutect2
- VIT | c.1590G>A p.T530= (on ENST00000389975 / NM_001177969.1; = p.T545= on NM_053276.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/226 reads (7%) | catalogued as rs887704550, COSV101007811; called by muse, mutect2
- VWA3A | c.1059C>T p.H353= | Silent (SNP) | VAF 84/223 reads (38%) | catalogued as rs200987727, COSV55387682; called by muse, mutect2, varscan2
- XKR7 | c.1509G>A p.V503= | Silent (SNP) | VAF 28/164 reads (17%) | called by muse, mutect2, varscan2
- XYLT1 | c.975G>A p.P325= | Silent (SNP) | VAF 72/237 reads (30%) | catalogued as rs761027921, COSV99763340; called by muse, mutect2, varscan2
- ZBTB18 | c.456A>G p.A152= | Silent (SNP) | VAF 29/407 reads (7%) | called by muse, mutect2
- ZFC3H1 | c.4215C>T p.C1405= | Silent (SNP) | VAF 57/193 reads (30%) | called by muse, mutect2, varscan2
- ZFHX4 | c.9501T>A p.P3167= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as rs1379072114, COSV50994089; called by muse, mutect2, varscan2
- ZFP28 | c.1086T>C p.I362= | Silent (SNP) | VAF 32/198 reads (16%) | called by muse, mutect2, varscan2
- ZFR2 | c.558C>T p.Y186= | Silent (SNP) | VAF 32/76 reads (42%) | catalogued as rs1281227136, COSV53597408; called by muse, mutect2, varscan2
- ZGPAT | c.567C>T p.R189= | Silent (SNP) | VAF 134/566 reads (24%) | catalogued as rs148025187; called by muse, mutect2, varscan2
- ZNF2 | c.1071C>T p.N357= (on ENST00000611147 / NM_001291605.2; = p.N344= on NM_021088.4) | Silent (SNP) | VAF 18/280 reads (6%) | catalogued as COSV54637002; called by muse, mutect2
- ZNF593 | c.51G>A p.R17= | Silent (SNP) | VAF 18/267 reads (7%) | catalogued as rs764747609; called by muse, mutect2
- ABCD1 | c.1081+120C>T | Intron (SNP) | VAF 22/273 reads (8%) | catalogued as rs781923749; called by muse, mutect2
- AC019294.1 | chr15:75775565 G>A | 5'Flank (SNP) | VAF 140/424 reads (33%) | called by muse, mutect2, varscan2
- AC244517.10 | c.36-8795C>T | Intron (SNP) | VAF 23/557 reads (4%) | catalogued as rs781943757, COSV73145211; called by muse, mutect2
- ADAMTS13 | c.825-37dup | Intron (INS) | VAF 79/368 reads (21%) | called by mutect2, pindel, varscan2
- AK2 | chr1:33008575 A>T | 3'Flank (SNP) | VAF 8/216 reads (4%) | called by muse, mutect2
- AL136439.1 | chr13:27666000 G>T | 3'Flank (SNP) | VAF 32/109 reads (29%) | called by muse, mutect2, varscan2
- AP1G1 | c.-4+901del | Intron (DEL) | VAF 42/145 reads (29%) | catalogued as rs749517248; called by mutect2, varscan2
- APBA2 | c.1524+69C>T | Intron (SNP) | VAF 57/187 reads (30%) | catalogued as rs777669163, COSV67105806; called by muse, mutect2, varscan2
- ARHGEF17 | c.3270+124C>T | Intron (SNP) | VAF 19/232 reads (8%) | catalogued as rs778350676; called by muse, mutect2
- ATAD3B | c.*716dup | 3'UTR (INS) | VAF 8/40 reads (20%) | catalogued as rs577360633; called by mutect2, pindel, varscan2
- ATP10B | c.470+1097C>A | Intron (SNP) | VAF 56/233 reads (24%) | called by muse, mutect2, varscan2
- C11orf21 | c.54-159dup | Intron (INS) | VAF 61/255 reads (24%) | called by mutect2, pindel, varscan2
- CAMK1 | c.1030+33G>T | Intron (SNP) | VAF 15/454 reads (3%) | called by muse, mutect2
- CCAR1 | c.-51+210dup | Intron (INS) | VAF 30/92 reads (33%) | called by mutect2, pindel, varscan2
- CD177P1 | n.165del | RNA (DEL) | VAF 14/100 reads (14%) | called by mutect2, varscan2
- CDKL1 | c.367-814G>T | Intron (SNP) | VAF 56/186 reads (30%) | called by muse, mutect2, varscan2
- CDX2 | c.541+1182C>T | Intron (SNP) | VAF 17/275 reads (6%) | called by muse, mutect2
- CFAP410 | c.78-616del | Intron (DEL) | VAF 25/151 reads (17%) | called by mutect2, pindel, varscan2
- CLU | c.*52del | 3'UTR (DEL) | VAF 75/274 reads (27%) | catalogued as rs748619722; called by mutect2, pindel, varscan2
- CPPED1 | c.*29A>T | 3'UTR (SNP) | VAF 92/273 reads (34%) | called by muse, mutect2, varscan2
- CREBL2 | c.*20C>T | 3'UTR (SNP) | VAF 8/61 reads (13%) | called by muse, mutect2, varscan2
- CTBP2 | c.58+12608G>A | Intron (SNP) | VAF 11/200 reads (6%) | called by muse, mutect2
- CTTN | c.*313G>A | 3'UTR (SNP) | VAF 122/336 reads (36%) | called by muse, varscan2
- CYS1 | chr2:10083919 C>T | 5'Flank (SNP) | VAF 45/141 reads (32%) | called by muse, mutect2, varscan2
- FAM20A | c.*1674T>C | 3'UTR (SNP) | VAF 20/160 reads (13%) | called by muse, mutect2, varscan2
- FAM47E | c.1105-3del | Intron (DEL) | VAF 15/84 reads (18%) | catalogued as rs528916918; called by mutect2, varscan2
- FGFR3 | chr4:1807525 C>A | 3'Flank (SNP) | VAF 50/196 reads (26%) | called by muse, mutect2, varscan2
- GLIPR1L2 | c.670+30del | Intron (DEL) | VAF 49/200 reads (25%) | catalogued as rs769479789; called by mutect2, pindel, varscan2
- GPATCH8 | c.*790del | 3'UTR (DEL) | VAF 78/237 reads (33%) | catalogued as rs755179686; called by mutect2, pindel, varscan2
- GSG1 | c.365-41del | Intron (DEL) | VAF 41/251 reads (16%) | catalogued as rs747639565; called by mutect2, pindel, varscan2
- HERC2P3 | n.1452dup | RNA (INS) | VAF 153/1324 reads (12%) | called by mutect2, pindel, varscan2
- HHIP | c.-2C>T | 5'UTR (SNP) | VAF 12/68 reads (18%) | catalogued as rs1386972226; called by muse, mutect2, varscan2
- HMGA2 | c.249+43287del | Intron (DEL) | VAF 60/366 reads (16%) | called by pindel, varscan2
- IL12RB1 | c.-78C>T | 5'UTR (SNP) | VAF 81/279 reads (29%) | catalogued as rs774754819; called by muse, mutect2, varscan2
- IQSEC1 | c.2847+1431del | Intron (DEL) | VAF 69/267 reads (26%) | catalogued as rs1221087395; called by mutect2, pindel, varscan2
- ITK | c.1450-18T>C | Intron (SNP) | VAF 287/380 reads (76%) | called by muse, mutect2, varscan2
- KCNA1 | c.*57dup | 3'UTR (INS) | VAF 85/267 reads (32%) | catalogued as rs767865722; called by mutect2, pindel, varscan2
- KCNAB1 | c.275+22338C>T | Intron (SNP) | VAF 50/148 reads (34%) | called by muse, mutect2, varscan2
- MDFIC | c.494-1217C>T | Intron (SNP) | VAF 19/255 reads (7%) | called by muse, mutect2
- MED14 | chrX:40735620 del G | 5'Flank (DEL) | VAF 104/465 reads (22%) | called by mutect2, pindel, varscan2
- MED26 | c.-15del | 5'UTR (DEL) | VAF 12/130 reads (9%) | catalogued as rs1305555599; called by mutect2, pindel
- MGAM | c.4618+1173C>T | Intron (SNP) | VAF 90/406 reads (22%) | catalogued as rs376478129; called by muse, mutect2, varscan2
- MRPL28 | c.288+318del | Intron (DEL) | VAF 34/135 reads (25%) | called by mutect2, pindel, varscan2
- MTCH1 | c.1098+24G>T | Intron (SNP) | VAF 65/369 reads (18%) | called by muse, mutect2, varscan2
- NIT2 | c.7+277T>C | Intron (SNP) | VAF 47/152 reads (31%) | called by muse, mutect2, varscan2
- NPHP1 | c.1926+352del | Intron (DEL) | VAF 64/188 reads (34%) | catalogued as rs112428035; called by mutect2, varscan2
- NUP188 | c.4434+159C>T | Intron (SNP) | VAF 16/382 reads (4%) | catalogued as rs1455774172; called by muse, mutect2
- OAT | c.772-10del | Intron (DEL) | VAF 35/220 reads (16%) | catalogued as rs778743727; called by mutect2, varscan2
- OBSCN | c.18662-2457C>T | Intron (SNP) | VAF 103/441 reads (23%) | called by muse, mutect2, varscan2
- P3H3 | c.1905+17del | Intron (DEL) | VAF 61/205 reads (30%) | called by mutect2, varscan2
- PCDHA10 | c.2388+4798G>A | Intron (SNP) | VAF 52/690 reads (8%) | catalogued as rs782122852, COSV100248424; called by muse, mutect2
- PCDHB6 | chr5:141157710 G>A | 3'Flank (SNP) | VAF 87/1142 reads (8%) | called by muse, mutect2
- PEX16 | c.*86G>A | 3'UTR (SNP) | VAF 162/566 reads (29%) | catalogued as rs146486656, COSV53797020; called by muse, mutect2, varscan2
- PEX19 | c.*1522C>T | 3'UTR (SNP) | VAF 59/469 reads (13%) | catalogued as rs1209374584; called by muse, mutect2, varscan2
- PITRM1 | c.56+482del | Intron (DEL) | VAF 46/242 reads (19%) | called by mutect2, pindel, varscan2
- PKD1 | c.11411+30C>T | Intron (SNP) | VAF 183/698 reads (26%) | catalogued as rs770380793; called by muse, mutect2, varscan2
- PKN1 | c.757-24dup | Intron (INS) | VAF 8/50 reads (16%) | called by mutect2, pindel
- PPP2R2D | c.198+384A>G | Intron (SNP) | VAF 115/325 reads (35%) | called by muse, mutect2, varscan2
- PPP2R3B | c.1036+251G>A | Intron (SNP) | VAF 165/450 reads (37%) | called by muse, mutect2, varscan2
- PPP2R3B | c.1036+24C>T | Intron (SNP) | VAF 233/613 reads (38%) | catalogued as COSV66812905; called by muse, mutect2, varscan2
- PTBP1 | c.-60G>T | 5'UTR (SNP) | VAF 16/416 reads (4%) | called by muse, mutect2
- RAB18 | c.*2372_*2375del | 3'UTR (DEL) | VAF 136/468 reads (29%) | catalogued as rs1205925073; called by pindel, varscan2
- RAD51D | c.*423del | 3'UTR (DEL) | VAF 38/221 reads (17%) | called by mutect2, varscan2
- RCOR3 | c.50-3412G>T | Intron (SNP) | VAF 13/109 reads (12%) | called by muse, mutect2, varscan2
- RER1 | c.366-58C>T | Intron (SNP) | VAF 134/456 reads (29%) | catalogued as rs750275813; called by muse, mutect2, varscan2
- RNF170 | c.*2181del | 3'UTR (DEL) | VAF 112/630 reads (18%) | called by mutect2, pindel, varscan2
- RNF5P1 | n.7G>A | RNA (SNP) | VAF 42/141 reads (30%) | catalogued as rs767908175; called by muse, mutect2
- RPS6KA5 | c.103+7965G>A | Intron (SNP) | VAF 42/104 reads (40%) | called by muse, varscan2
- SBF2 | c.5231+23C>T | Intron (SNP) | VAF 117/424 reads (28%) | called by muse, mutect2, varscan2
- SELENOI | chr2:26346142 T>G | 5'Flank (SNP) | VAF 7/198 reads (4%) | called by muse, mutect2
- SLC23A1 | c.-41C>T | 5'UTR (SNP) | VAF 32/120 reads (27%) | catalogued as rs780524051; called by muse, mutect2, varscan2
- SLC2A14 | c.88-7086G>A | Intron (SNP) | VAF 11/246 reads (4%) | catalogued as rs1348988878, COSV61587875; called by muse, mutect2
- SLCO3A1 | c.181-26806G>A | Intron (SNP) | VAF 11/143 reads (8%) | catalogued as rs1486240294; called by muse, mutect2
- SNHG10 | chr14:95517201 del G | 3'Flank (DEL) | VAF 12/105 reads (11%) | called by mutect2, pindel
- SNORD115-3 | n.38G>T | RNA (SNP) | VAF 70/321 reads (22%) | catalogued as rs777773854; called by muse, mutect2, varscan2
- SNX29 | c.2318+2522del | Intron (DEL) | VAF 33/104 reads (32%) | catalogued as rs759376406; called by mutect2, varscan2
- STXBP4 | c.945+330G>A | Intron (SNP) | VAF 20/153 reads (13%) | called by muse, mutect2, varscan2
- TAAR3P | n.606C>T | RNA (SNP) | VAF 51/227 reads (22%) | called by muse, mutect2, varscan2
- TBCB | c.547+103G>A | Intron (SNP) | VAF 11/247 reads (4%) | catalogued as rs1464433731; called by muse, mutect2
- TCAF2 | c.1615+257C>T | Intron (SNP) | VAF 39/96 reads (41%) | called by muse, mutect2, varscan2
- TM4SF19 | chr3:196320066 C>T | 3'Flank (SNP) | VAF 8/67 reads (12%) | catalogued as rs775754566; called by muse, varscan2
- TRAC | c.*133del | 3'UTR (DEL) | VAF 39/118 reads (33%) | catalogued as rs747854238; called by mutect2, varscan2
- TSPAN32 | c.544-302G>A | Intron (SNP) | VAF 152/493 reads (31%) | catalogued as rs770699882; called by muse, mutect2, varscan2
- UBR4 | c.15009-216G>T | Intron (SNP) | VAF 40/81 reads (49%) | called by muse, mutect2
- ZFHX4 | c.3093+97del | Intron (DEL) | VAF 18/132 reads (14%) | catalogued as rs751858242; called by mutect2, varscan2
- ZFYVE27 | c.197+42G>A | Intron (SNP) | VAF 79/278 reads (28%) | catalogued as rs761622947; called by muse, mutect2, varscan2
- ZNF175 | c.*1102del | 3'UTR (DEL) | VAF 39/318 reads (12%) | called by mutect2, pindel, varscan2
- ZNF862 | c.1118-49G>A | Intron (SNP) | VAF 19/217 reads (9%) | catalogued as rs373791129; called by muse, mutect2
